Somatic mutation profile of tumor specimen ALCH-B36F-TTP1-A (aliquot ALCH-B36F-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B36F, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 57.8 years (21,123 days).
Specimen ALCH-B36F-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 982f49bb-6566-45b9-a709-82576539790f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B36F-NB1-A (Blood Derived Normal), aliquot ALCH-B36F-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f6f382e-5a94-4ccb-9736-878780b37810

The open-access MAF lists 138 somatic variants for this specimen: 95 protein-altering or splice-affecting, 30 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 30, Intron 6, Nonsense Mutation 5, RNA 5, Splice Region 2, Splice Site 2, Frame Shift Del 2, 3'Flank 1, Translation Start Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS2 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 14/159 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs746405628; called by muse, mutect2
- ADGRD2 | c.1674G>T p.W558C | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440523892; called by muse, mutect2, varscan2
- CELF4 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867841498; called by muse, mutect2
- CHRM2 | c.920C>A p.T307K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.077); catalogued as COSV100280591; called by muse, mutect2
- COL25A1 | c.1198-1G>A p.X400_splice | Splice Site (SNP) | VAF 19/238 reads (8%) | catalogued as COSV101211722, COSV67649261; called by muse, mutect2
- COL4A5 | c.1118G>T p.R373L | Missense Mutation (SNP) | VAF 14/155 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.392); catalogued as COSV60363347; called by muse, mutect2
- DCAF12L1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV64421788; called by muse, mutect2
- DCAF4L2 | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV60480306; called by muse, mutect2, varscan2
- DSCAML1 | c.1828C>G p.R610G (on ENST00000321322; = p.R550G on NM_020693.4) | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58385083, COSV58392788; called by muse, mutect2
- FAM135B | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.978); catalogued as COSV50541678; called by muse, mutect2
- FGFR2 | c.1614G>T p.M538I | Missense Mutation (SNP) | VAF 24/231 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100336304; called by muse, mutect2
- L1TD1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.066); catalogued as rs1383461786; called by muse, mutect2, varscan2
- LRRC66 | c.830G>T p.W277L | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100602973; called by muse, mutect2
- MKI67 | c.2183A>G p.H728R | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as rs1039822838; called by muse, mutect2
- MOB3B | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1270521192, COSV51783879; called by muse, mutect2
- PITPNC1 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.982); catalogued as rs1273181315, COSV100083958; called by muse, mutect2, varscan2
- PLXNA3 | c.1408C>A p.P470T | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.999); catalogued as COSV63755076; called by muse, mutect2, varscan2
- RAB5B | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/159 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); catalogued as COSV100822065; called by muse, mutect2
- SCNN1G | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55597909; called by muse, mutect2, varscan2
- USP13 | c.1737A>T p.E579D | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55866169; called by muse, mutect2
- ZNF800 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56175698; called by muse, mutect2
- ZSCAN4 | c.105A>T p.R35S | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs773307267; called by muse, mutect2, varscan2
- ABCA13 | c.91T>C p.F31L | Missense Mutation (SNP) | VAF 13/319 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2
- AC100868.1 | c.1873C>A p.P625T | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.051); called by muse, mutect2
- ADPRH | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AK5 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.175); called by muse, mutect2
- ASXL3 | c.4040G>T p.G1347V | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ATP11C | c.511G>C p.D171H | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- AWAT1 | c.704G>A p.S235N | Missense Mutation (SNP) | VAF 22/295 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- C16orf78 | c.505C>A p.Q169K | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf96 | c.664A>G p.S222G | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.083); called by muse, mutect2
- CACNA2D2 | c.3172G>A p.E1058K (on ENST00000479441 / NM_001174051.3; = p.E1051K on NM_006030.4) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, varscan2
- CBFA2T3 | c.1717G>T p.A573S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CGRRF1 | c.174A>C p.K58N | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.563); called by muse, mutect2
- CILK1 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CLCN7 | c.1708A>G p.M570V | Missense Mutation (SNP) | VAF 22/201 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- CMYA5 | c.2926A>T p.I976L | Missense Mutation (SNP) | VAF 19/166 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CNBD1 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.058); called by muse, mutect2
- COL22A1 | c.4144G>A p.V1382I | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A1 | c.3460G>T p.G1154C | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPP6 | c.792C>A p.Y264* (on ENST00000377770 / NM_001364500.2; = p.Y202* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- ELAPOR2 | c.440C>T p.S147F | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2
- ERBB4 | c.3358C>G p.Q1120E | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated (0.97); PolyPhen benign (0.006); called by muse, mutect2
- F11R | c.56T>G p.I19S | Missense Mutation (SNP) | VAF 33/302 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FARS2 | c.882G>T p.M294I | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.204); called by muse, mutect2
- FAT1 | c.6585C>G p.I2195M | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- FLG | c.10454C>A p.A3485D | Missense Mutation (SNP) | VAF 45/245 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FTSJ3 | c.1378G>T p.V460F | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.087); called by muse, mutect2
- GALNT11 | c.1156T>C p.Y386H | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, mutect2
- GORAB | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 47/312 reads (15%) | called by muse, mutect2, varscan2
- GPR119 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GPRASP2 | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GUCY2C | c.689A>T p.K230M | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.421); called by muse, mutect2
- HECTD4 | c.5752G>T p.E1918* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | called by muse, mutect2, varscan2
- IFT172 | c.2642+1G>T p.X881_splice | Splice Site (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- IGHD2-15 | c.25C>A p.L9I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | called by muse, mutect2
- IGHM | c.1388T>A p.F463Y | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- IL17F | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 19/218 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); called by muse, mutect2
- ITGAX | c.204G>C p.Q68H | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.328); called by muse, mutect2
- KCNH2 | c.462G>C p.W154C | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.19); called by muse, mutect2
- KEAP1 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- LCP2 | c.924A>T p.P308= | Splice Region (SNP) | VAF 8/51 reads (16%) | called by muse, varscan2
- LILRA2 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 11/165 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.056); called by muse, mutect2
- LYZ | c.257G>C p.G86A | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); called by muse, mutect2
- MAGEB6B | c.310C>A p.Q104K | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.034); called by muse, mutect2
- MC3R | c.917T>C p.L306S | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- MED13 | c.3193A>G p.I1065V | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.891); called by muse, mutect2
- MTMR1 | c.422G>T p.R141M | Missense Mutation (SNP) | VAF 17/185 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- NOL8 | c.470A>G p.N157S | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NR0B1 | c.1327G>T p.V443F | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- OR10C1 | c.852del p.I285Sfs*18 (on ENST00000622521; = p.I283Sfs*18 on NM_013941.3) | Frame Shift Del (DEL) | VAF 18/162 reads (11%) | called by mutect2, varscan2
- OR2AJ1 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- OR6K3 | c.431A>G p.N144S (on ENST00000368146; = p.N128S on NM_001005327.2) | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- PHF3 | c.5867A>T p.D1956V | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2
- PRMT8 | c.1108C>T p.L370F | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- RAB33A | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- RASGEF1C | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 20/234 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.14); called by muse, mutect2
- RNF182 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLITRK4 | c.2222G>A p.S741N | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SNX17 | c.681+3G>A | Splice Region (SNP) | VAF 18/125 reads (14%) | called by muse, mutect2, varscan2
- SP9 | c.799T>C p.Y267H | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.73); called by muse, mutect2
- STRIP2 | c.151C>G p.L51V | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); called by muse, mutect2
- TDRD5 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- TEX13C | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.86); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- TF | c.1408del p.H470Ifs*53 | Frame Shift Del (DEL) | VAF 26/129 reads (20%) | called by mutect2, pindel, varscan2
- THSD7A | c.2924C>A p.P975Q | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2
- THSD7A | c.2923C>A p.P975T | Missense Mutation (SNP) | VAF 24/294 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- TINF2 | c.215A>C p.Q72P | Missense Mutation (SNP) | VAF 28/277 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.434); called by muse, mutect2
- TNC | c.663C>A p.C221* | Nonsense Mutation (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- TRAF3IP2 | c.332T>C p.L111P | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- TTN | c.4003G>A p.E1335K (on ENST00000591111; = p.E1289K on NM_003319.4) | Missense Mutation (SNP) | VAF 9/100 reads (9%) | PolyPhen benign (0.178); called by muse, mutect2
- UNC13B | c.4371G>A p.M1457I | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF311 | c.562G>T p.D188Y | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2
- ZNF354B | c.1433G>T p.S478I | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.063); called by muse, mutect2
- ZNF689 | c.50G>T p.R17I | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ABCC8 | c.1719C>A p.P573= | Silent (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- AXDND1 | c.210G>C p.A70= | Silent (SNP) | VAF 29/210 reads (14%) | called by muse, mutect2, varscan2
- CABLES1 | c.1146C>A p.I382= (on ENST00000256925 / NM_001100619.2; = p.I117= on NM_138375.2) | Silent (SNP) | VAF 21/351 reads (6%) | called by muse, mutect2
- CSMD3 | c.3960T>A p.L1320= (on ENST00000297405 / NM_001363185.1; = p.L1216= on NM_052900.3) | Silent (SNP) | VAF 12/208 reads (6%) | called by muse, mutect2
- DCAF5 | c.189C>T p.N63= | Silent (SNP) | VAF 14/78 reads (18%) | called by mutect2, varscan2
- DDX4 | c.12A>G p.E4= | Silent (SNP) | VAF 18/238 reads (8%) | called by muse, mutect2
- DNAH5 | c.3000T>C p.S1000= | Silent (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- FBXO47 | c.1266A>G p.R422= | Silent (SNP) | VAF 16/168 reads (10%) | called by muse, mutect2
- KDR | c.2310C>T p.G770= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- KIF16B | c.2127C>A p.L709= | Silent (SNP) | VAF 48/474 reads (10%) | called by muse, mutect2
- LAMA5 | c.9735C>T p.L3245= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1485098181; called by muse, mutect2, varscan2
- MCF2L2 | c.870C>A p.T290= | Silent (SNP) | VAF 29/131 reads (22%) | called by muse, varscan2
- NSDHL | c.951C>G p.V317= | Silent (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- OR11L1 | c.390C>A p.L130= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as COSV100869442; called by muse, mutect2, varscan2
- OR4C3 | c.48A>C p.S16= | Silent (SNP) | VAF 8/162 reads (5%) | catalogued as COSV100168410; called by muse, mutect2
- OTOG | c.264C>G p.A88= | Silent (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- PCDHA8 | c.1509G>A p.S503= | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV65330748; called by muse, mutect2
- PCDHGB4 | c.453A>C p.R151= | Silent (SNP) | VAF 11/93 reads (12%) | called by muse, mutect2, varscan2
- RFX6 | c.327C>T p.T109= | Silent (SNP) | VAF 11/298 reads (4%) | catalogued as rs1444500835; called by muse, mutect2
- RYR1 | c.13701C>A p.A4567= | Silent (SNP) | VAF 28/444 reads (6%) | called by muse, mutect2
- SCML1 | c.273T>G p.R91= (on ENST00000380041 / NM_001037540.3; = p.R64= on NM_006746.6) | Silent (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- SLC35F1 | c.936C>A p.V312= | Silent (SNP) | VAF 12/203 reads (6%) | catalogued as COSV64503404; called by muse, mutect2
- SPANXD | c.78G>C p.P26= | Silent (SNP) | VAF 19/281 reads (7%) | catalogued as rs201199081, COSV100982311; called by muse, mutect2
- SPTBN4 | c.2478C>A p.R826= | Silent (SNP) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- THEM4 | c.357G>A p.L119= | Silent (SNP) | VAF 34/271 reads (13%) | called by muse, mutect2, varscan2
- TMED8 | c.234G>A p.T78= | Silent (SNP) | VAF 18/178 reads (10%) | catalogued as rs755924755; called by muse, mutect2, varscan2
- UHRF1BP1L | c.135A>T p.V45= | Silent (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- USP6 | c.2472A>C p.L824= | Silent (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- ZAN | c.1218C>T p.G406= | Silent (SNP) | VAF 12/118 reads (10%) | called by muse, mutect2, varscan2
- ZCWPW1 | c.561C>A p.G187= | Silent (SNP) | VAF 9/227 reads (4%) | called by muse, mutect2
- AC024940.1 | n.1062A>G | RNA (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- AC092118.1 | n.807G>C | RNA (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- ADGRD1 | c.2109-39A>C | Intron (SNP) | VAF 24/206 reads (12%) | called by muse, mutect2, varscan2
- ADGRE4P | n.223G>T | RNA (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- ARPC3 | c.*10G>T | 3'UTR (SNP) | VAF 41/355 reads (12%) | catalogued as COSV57399906, COSV57400374; called by muse, mutect2, varscan2
- CDC42BPB | c.3811+335A>T | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- FAM74A3 | n.163C>A | RNA (SNP) | VAF 40/506 reads (8%) | catalogued as rs374588817; called by muse, mutect2
- HBD | chr11:5232772 T>A | 3'Flank (SNP) | VAF 15/153 reads (10%) | called by muse, mutect2, varscan2
- IQSEC2 | c.2460-48T>C | Intron (SNP) | VAF 6/103 reads (6%) | called by muse, mutect2
- NMT2 | c.110+13433A>C | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- RYR2 | c.11146-1185G>T | Intron (SNP) | VAF 22/158 reads (14%) | called by muse, mutect2, varscan2
- SSPOP | n.4031C>T | RNA (SNP) | VAF 9/71 reads (13%) | catalogued as COSV50487161; called by muse, mutect2, varscan2
- TM4SF19 | c.450-35C>A | Intron (SNP) | VAF 18/240 reads (8%) | catalogued as rs552776116; called by muse, mutect2
